Somatic mutation profile of tumor specimen MMRF_2580_1_BM_CD138pos (aliquot MMRF_2580_1_BM_CD138pos_T1_KHS5U_L13277) from MMRF case MMRF_2580, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.4 years (29,358 days).
Specimen MMRF_2580_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afebf9d5-c9aa-4f3b-8efa-0515c6eee6a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2580_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2580_1_PB_WBC_C3_KHS5U_L13278; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c852721-0873-4982-a0ac-d34495fa74e0

The open-access MAF lists 103 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 22, Silent 14, Intron 12, 5'Flank 5, Frame Shift Del 4, Nonsense Mutation 3, 5'UTR 3, Splice Region 2, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C5AR1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs199583435; called by muse, mutect2, varscan2
- CALCOCO1 | c.1008C>T p.A336= | Splice Region (SNP) | VAF 24/66 reads (36%) | catalogued as rs573432857; called by muse, mutect2, varscan2
- CFAP69 | c.972A>C p.E324D | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as rs761696915; called by muse, mutect2, varscan2
- DIS3 | c.1400G>A p.R467Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201674523, COSV66706858; called by muse, mutect2, varscan2
- DIS3 | c.987+1G>C p.X329_splice | Splice Site (SNP) | VAF 3/40 reads (8%) | catalogued as COSV66706961, COSV66708360; called by muse, mutect2
- HECW1 | c.4553C>T p.A1518V | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as rs764635959, COSV67824434; called by muse, mutect2, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2
- IGLV3-1 | c.313T>C p.Y105H | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs574479963; called by muse, varscan2
- KCTD3 | c.1792C>A p.Q598K | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV52065584; called by muse, mutect2, varscan2
- KLHL38 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs1328447683; called by muse, mutect2
- MYO10 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as rs1334046909; called by muse, mutect2, varscan2
- MZT2A | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs777626407, COSV58312238; called by muse, mutect2, varscan2
- PCDH7 | c.2753A>G p.D918G | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs958086792, COSV62337065; called by muse, mutect2, varscan2
- PLXND1 | c.5654G>A p.R1885Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.998); catalogued as rs369952557; called by muse, mutect2, varscan2
- PRDM8 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs567872310; called by muse, mutect2
- PREX2 | c.2268G>T p.W756C | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99906503; called by muse, mutect2
- ROR1 | c.2230G>A p.V744I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs150607362; called by muse, mutect2, varscan2
- SUZ12 | c.646A>C p.N216H | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59498309; called by muse, mutect2, varscan2
- ZNF451 | c.1994T>C p.I665T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs756076400; called by muse, mutect2, varscan2
- AL592490.1 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- CEP63 | c.1856A>T p.K619I | Missense Mutation (SNP) | VAF 68/194 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CIC | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CMYA5 | c.6314del p.S2105* | Frame Shift Del (DEL) | VAF 43/257 reads (17%) | called by mutect2, pindel, varscan2
- COBLL1 | c.1357C>G p.L453V (on ENST00000392717; = p.L415V on NM_014900.5) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CPAMD8 | c.3873G>T p.Q1291H (on ENST00000651564; = p.Q1244H on NM_015692.5) | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBBP | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- GFPT2 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 16/484 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.384); called by muse, mutect2
- IGKV5-2 | c.199A>C p.I67L | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- LNPK | c.890G>C p.R297P | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LPAR5 | c.643T>C p.F215L | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ME3 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, varscan2
- MEIS1 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- OR5M1 | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 88/253 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR9A2 | c.107T>G p.V36G | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- PIGN | c.629_632del p.L210* | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- SPN | c.69del p.V24Cfs*17 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel*, varscan2
- TENT5C | c.136_139del p.I46Lfs*2 | Frame Shift Del (DEL) | VAF 36/185 reads (19%) | called by mutect2, pindel, varscan2
- TMEM116 | c.-66-26_-56del | Splice Site (DEL) | VAF 60/165 reads (36%) | called by mutect2, pindel
- TRIM6-TRIM34 | c.1411T>G p.W471G | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- TRMT1L | c.1321A>T p.R441* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- TRPV6 | c.346+8G>A | Splice Region (SNP) | VAF 17/103 reads (17%) | called by muse, mutect2, varscan2
- XPO1 | c.583A>T p.K195* | Nonsense Mutation (SNP) | VAF 3/7 reads (43%) | called by muse, mutect2
- XPO1 | c.313T>A p.Y105N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ZFYVE26 | c.2240A>G p.H747R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF804B | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 25/273 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2
- ZNF829 | c.787A>C p.T263P | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- ASXL3 | c.1701C>A p.T567= | Silent (SNP) | VAF 52/199 reads (26%) | called by muse, mutect2, varscan2
- BICRA | c.2067C>T p.A689= | Silent (SNP) | VAF 17/109 reads (16%) | called by muse, mutect2, varscan2
- CAMK1G | c.858C>T p.D286= | Silent (SNP) | VAF 63/239 reads (26%) | catalogued as rs752095459; called by muse, mutect2, varscan2
- COL19A1 | c.1905A>G p.G635= | Silent (SNP) | VAF 36/123 reads (29%) | called by muse, mutect2, varscan2
- DOCK10 | c.3603A>T p.I1201= | Silent (SNP) | VAF 39/172 reads (23%) | called by muse, mutect2, varscan2
- DSC3 | c.1404G>T p.G468= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as rs1288214254; called by muse, mutect2, varscan2
- MAML2 | c.1974G>A p.Q658= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs571656416, COSV73262854, COSV73262892; called by mutect2, varscan2
- PLEKHA4 | c.1521C>T p.D507= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- RXRA | c.48C>T p.N16= | Silent (SNP) | VAF 136/247 reads (55%) | catalogued as rs755375514; called by muse, mutect2, varscan2
- ST8SIA6 | c.219G>A p.K73= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV101111582; called by muse, mutect2, varscan2
- STARD13 | c.378A>G p.Q126= (on ENST00000336934 / NM_001243476.3; = p.Q8= on NM_052851.3) | Silent (SNP) | VAF 95/181 reads (52%) | called by muse, mutect2, varscan2
- TREH | c.1365C>G p.L455= | Silent (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- TRHDE | c.2754T>C p.D918= | Silent (SNP) | VAF 36/117 reads (31%) | catalogued as COSV53843660; called by muse, mutect2, varscan2
- WWTR1 | c.699G>A p.Q233= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV62291577; called by muse, mutect2
- ABCB9 | c.-463C>T | 5'UTR (SNP) | VAF 2/8 reads (25%) | called by muse, mutect2
- ABHD6 | c.*170C>G | 3'UTR (SNP) | VAF 49/61 reads (80%) | called by muse, mutect2, varscan2
- AC120036.1 | n.104+5641G>A | Intron (SNP) | VAF 22/60 reads (37%) | called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551194 A>G | 5'Flank (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- ADAM12 | c.*3282A>C | 3'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- BACH2 | c.*673G>T | 3'UTR (SNP) | VAF 10/88 reads (11%) | called by muse, varscan2
- BCL7A | chr12:122021032 A>G | 5'Flank (SNP) | VAF 40/130 reads (31%) | called by muse, varscan2
- BCL7A | chr12:122021076 G>T | 5'Flank (SNP) | VAF 44/132 reads (33%) | called by muse, varscan2
- BTNL9 | c.*1405A>G | 3'UTR (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2, varscan2
- CASQ2 | c.*427A>G | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- CTF1 | c.*731_*735dup | 3'UTR (INS) | VAF 30/114 reads (26%) | called by mutect2, varscan2
- CUL9 | c.6847-115T>C | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, varscan2
- DDX39B | c.-2-133C>T | Intron (SNP) | VAF 8/37 reads (22%) | catalogued as rs1479610997; called by muse, mutect2, varscan2
- DTYMK | c.*116G>A | 3'UTR (SNP) | VAF 3/43 reads (7%) | catalogued as rs1228089405; called by muse, mutect2
- EGR1 | c.-126G>A | 5'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53520591; called by muse, mutect2, varscan2
- EPS15L1 | c.1193+95del | Intron (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- ESRRG | c.*615del | 3'UTR (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- FAM184A | c.1815+569C>T | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- FAM216B | c.*1690A>G | 3'UTR (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- FGF7 | c.*2633T>C | 3'UTR (SNP) | VAF 32/55 reads (58%) | called by muse, mutect2, varscan2
- FICD | c.301+20T>A | Intron (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- IAPP | c.*1332A>G | 3'UTR (SNP) | VAF 19/51 reads (37%) | called by muse, mutect2, varscan2
- IL21R | c.*843A>G | 3'UTR (SNP) | VAF 26/107 reads (24%) | called by muse, mutect2, varscan2
- KCNJ18 | c.*195G>A | 3'UTR (SNP) | VAF 21/81 reads (26%) | catalogued as rs1252348562; called by muse, mutect2, varscan2
- KIAA1958 | c.*8494A>G | 3'UTR (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- LANCL1 | chr2:210476733 G>A | 5'Flank (SNP) | VAF 45/134 reads (34%) | catalogued as rs904596561; called by muse, mutect2, varscan2
- MAP4K3 | c.97-1669T>A | Intron (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2, varscan2
- MED19 | c.-111T>C | 5'UTR (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- MEN1 | c.839+27C>T | Intron (SNP) | VAF 32/86 reads (37%) | catalogued as rs372668380; called by muse, mutect2, varscan2
- NCEH1 | c.*1887T>C | 3'UTR (SNP) | VAF 19/113 reads (17%) | catalogued as COSV99860485; called by muse, mutect2, varscan2
- PHF24 | c.*2973G>A | 3'UTR (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- RASGRP2 | c.1296+74C>G | Intron (SNP) | VAF 30/133 reads (23%) | called by muse, mutect2, varscan2
- RPL23 | c.13+272G>A | Intron (SNP) | VAF 65/202 reads (32%) | catalogued as rs1221021041; called by muse, mutect2, varscan2
- RPS6 | c.138+228A>G | Intron (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- SEL1L | c.*4738G>A | 3'UTR (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- SEPTIN11 | chr4:77039127 T>G | 3'Flank (SNP) | VAF 90/281 reads (32%) | called by muse, mutect2, varscan2
- SLC6A3 | c.*1453G>A | 3'UTR (SNP) | VAF 55/296 reads (19%) | catalogued as rs1285326678; called by muse, mutect2, varscan2
- SOX11 | c.*1223G>A | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- SRA1 | c.*110C>T | 3'UTR (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- TPM1 | c.851+546G>A | Intron (SNP) | VAF 11/33 reads (33%) | catalogued as rs978241300; called by muse, mutect2
- TSEN2 | c.*164G>A | 3'UTR (SNP) | VAF 58/96 reads (60%) | called by muse, mutect2, varscan2
- URB1 | chr21:32393335 C>T | 5'Flank (SNP) | VAF 48/139 reads (35%) | catalogued as rs1026039201; called by muse, mutect2, varscan2
- ZNF141 | c.*10993T>A | 3'UTR (SNP) | VAF 89/249 reads (36%) | called by muse, mutect2, varscan2
